Somatic mutation profile of tumor specimen TCGA-KM-8442-01A (aliquot TCGA-KM-8442-01A-11D-2310-10) from TCGA case TCGA-KM-8442, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 38.9 years (14,212 days).
Specimen TCGA-KM-8442-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a958b3cc-dd6b-4ddc-970c-27e5af8321d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KM-8442-10A (Blood Derived Normal), aliquot TCGA-KM-8442-10A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cedc0a47-85ef-4bea-9f7a-29b1a73f3908

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 7, Frame Shift Del 3, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL1 | c.3640T>A p.W1214R | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65892984; called by muse, mutect2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | catalogued as rs766714372; called by mutect2, varscan2
- EPHA1 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99314567; called by muse, mutect2
- MOV10L1 | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140536899; called by muse, mutect2, varscan2
- OR4C12 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs774365305; called by muse, mutect2, varscan2
- OR4X1 | c.128T>C p.I43T | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs144193033; called by muse, mutect2, varscan2
- PIWIL3 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs574938118, COSV59996172; called by muse, mutect2
- SNAPIN | c.84del p.L29Cfs*24 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs34568420; called by mutect2, pindel, varscan2
- CIITA | c.3118C>T p.P1040S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- SLC7A3 | c.1830T>A p.D610E | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZRANB1 | c.753del p.K251Nfs*2 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by pindel, varscan2
- CACNA1F | c.1107C>T p.G369= | Silent (SNP) | VAF 90/97 reads (93%) | catalogued as rs782706571; called by muse, mutect2, varscan2
- KDM3A | c.1233T>G p.T411= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100460849; called by muse, mutect2, varscan2
- MAP3K10 | c.1872C>T p.S624= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs771698539, COSV53421609; called by muse, mutect2, varscan2
- MORN1 | c.1128G>A p.P376= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs750153953; called by muse, mutect2, varscan2
- MPZL3 | c.84C>T p.I28= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs565159411, COSV54053586; called by muse, mutect2, varscan2
- PRDM9 | c.366G>A p.A122= | Silent (SNP) | VAF 57/66 reads (86%) | catalogued as rs766083673, COSV57008152, COSV57010953; called by muse, mutect2, varscan2
- TM7SF3 | c.255T>C p.L85= | Silent (SNP) | VAF 3/51 reads (6%) | called by muse, mutect2
- AP1S3 | c.183-69G>A | Intron (SNP) | VAF 4/40 reads (10%) | catalogued as rs568343914; called by mutect2, varscan2
- LINC01587 | n.177T>C | RNA (SNP) | VAF 41/122 reads (34%) | catalogued as rs1356425852; called by muse, mutect2, varscan2
